HCMI case HCM-CSHL-0807-C54 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Uterus, NOS. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/77e36a58-fc44-4b8a-a81c-173362967082

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Days to birth: -23,343 days (63.9 years before the index date); Year of birth: 1957; Vital status: Alive.

Diagnoses (1)
1. Carcinoma, undifferentiated, NOS: ICD-O-3 morphology code: 8020/3; ICD-10 code: C54.1; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Classification of tumor: primary; AJCC staging edition: 8th; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Peritoneal fluid cytological status: Non-Malignant; Sites of involvement: Pelvic Lymph Node(s) / Lymph node, NOS / Uterus.
   Pathology details: Lymph node involvement: Negative; Lymphatic invasion present: Yes; Tumor largest dimension diameter: 3.8 cm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 39 days; Days to treatment end: 145 days.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 185 days; Days to treatment end: 199 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Pelvic lymph nodes; Days to progression: 0 days.
- Days to follow up: 456 days (1.2 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 30.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.
- ESR1 (IHC): Negative.
- MLH1 (IHC): Negative.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PGR (IHC): Negative.
- PMS2 (IHC): Negative.
- TP53 (IHC): Normal.
- Test (Microsatellite Analysis): Low.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS / Hypothyroidism; Risk factors: Diabetes, NOS / Adenomyosis.
- Timepoint category: Initial Diagnosis; Weight: 76.2 kg; Height: 157.5 cm; BMI: 30.7.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0807-C54-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0807-C54-01A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
  Slide HCM-CSHL-0807-C54-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample HCM-CSHL-0807-C54-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0807-C54-11A-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 3; Percent necrosis: 0; Percent stromal cells: 97; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0807-C54-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
